Somatic mutation profile of tumor specimen TCGA-29-1710-01A (aliquot TCGA-29-1710-01A-02W-0633-09) from TCGA case TCGA-29-1710, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.7 years (19,969 days).
Specimen TCGA-29-1710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e28d9e43-9f3d-4af3-8af0-9f9512b9e791.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1710-10A (Blood Derived Normal), aliquot TCGA-29-1710-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d134e9-9f9e-43b3-aaf1-0c36d66c8513

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 80/168 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACA | c.71_74del p.V24Efs*3 | Frame Shift Del (DEL) | VAF 16/188 reads (9%) | catalogued as rs752401577; called by mutect2, pindel
- ADAD1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113377246, COSV56641769, COSV56643052; called by muse, mutect2, varscan2
- ADAM23 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs199943814, COSV52213788; called by muse, mutect2, varscan2
- ADGRB2 | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57072963; called by muse, mutect2, varscan2
- ADGRG7 | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56295776; called by muse, mutect2, varscan2
- ARHGAP15 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54492714; called by muse, mutect2, varscan2
- ARSF | c.1496C>A p.T499N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV63839446; called by muse, mutect2, varscan2
- DOCK5 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766466638, COSV52399348; called by muse, mutect2, varscan2
- DPP3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64756549, COSV64758166; called by muse, mutect2, varscan2
- EXO5 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs753110243, COSV56416132; called by muse, mutect2
- FAT2 | c.9368T>C p.F3123S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55818450; called by muse, mutect2, varscan2
- GOLGA7B | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101002337, COSV65428853; called by muse, mutect2
- HNRNPR | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs764215177, COSV56421091; called by muse, mutect2, varscan2
- ILF3 | c.2400C>A p.D800E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51556791; called by muse, mutect2, varscan2
- MFSD5 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs911171862, COSV100288893; called by muse, mutect2
- MGA | c.9136_9158del p.L3046Gfs*28 (on ENST00000219905 / NM_001164273.1; = p.L2837Gfs*28 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as COSV54952800; called by mutect2, pindel, varscan2
- MYH8 | c.89A>C p.Q30P | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV101238782, COSV67963898; called by muse, mutect2, varscan2
- MYL10 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56207678; called by muse, mutect2, varscan2
- NBPF1 | c.2206G>C p.A736P | Missense Mutation (SNP) | VAF 106/2450 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767008324, COSV99844001; called by muse, mutect2
- OR2G6 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV58574016; called by muse, mutect2
- OR2T4 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 42/417 reads (10%) | catalogued as rs1272812025, COSV100822387; called by muse, mutect2
- OR8B4 | c.559del p.S187Pfs*18 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | catalogued as COSV62069627; called by mutect2, pindel
- PLA2R1 | c.4100C>A p.S1367Y | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV51775830, COSV99322015; called by muse, mutect2
- PSMB9 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 522/866 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66399495; called by muse, mutect2, varscan2
- RBM46 | c.1321A>T p.S441C | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV55978413; called by muse, mutect2, varscan2
- RINL | c.349G>A p.D117N (on ENST00000591812 / NM_001195833.2; = p.D3N on NM_198445.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV61574543; called by muse, mutect2, varscan2
- RNF20 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 26/204 reads (13%) | catalogued as rs1230447114, COSV66355636; called by muse, mutect2, varscan2
- SLC16A1 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV63708520, COSV63709176; called by muse, mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 14/119 reads (12%) | catalogued as rs750181498; called by mutect2, varscan2
- TROAP | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530742403, COSV57743819; called by muse, mutect2, varscan2
- UBAC2 | c.862G>A p.V288I (on ENST00000403766 / NM_001144072.2; = p.V253I on NM_177967.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs765235078, COSV63117812; called by muse, mutect2, varscan2
- VWA8 | c.1531G>T p.V511F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV55696007; called by muse, mutect2, varscan2
- ZNF14 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100693956; called by muse, mutect2
- ZNF488 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs536291384; called by muse, mutect2, varscan2
- ZNF548 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV60240530; called by muse, mutect2
- SLC6A11 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); called by muse, mutect2
- CHD7 | c.405G>A p.G135= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV71109568; called by muse, mutect2, varscan2
- DKK3 | c.268T>C p.L90= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV58868417; called by muse, mutect2, varscan2
- DMXL2 | c.8811G>A p.T2937= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs147864837, COSV51844977; called by muse, mutect2, varscan2
- DOCK6 | c.1062C>T p.C354= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV52948855; called by muse, mutect2, varscan2
- EPHA6 | c.2814C>A p.A938= | Silent (SNP) | VAF 25/220 reads (11%) | catalogued as COSV67569812; called by muse, mutect2, varscan2
- GPR55 | c.306C>T p.F102= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs144507378; called by muse, mutect2, varscan2
- MAP11 | c.807C>T p.V269= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV57586181; called by muse, mutect2, varscan2
- NUP98 | c.1494G>A p.Q498= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100261421, COSV61437550; called by muse, mutect2
- PLEKHH2 | c.3309G>A p.R1103= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as COSV56752640; called by muse, mutect2, varscan2
- RPL3L | c.246G>A p.P82= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs377420235; called by muse, mutect2, varscan2
- ZBTB20 | c.1227C>T p.P409= (on ENST00000474710 / NM_001164342.2; = p.P336= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs752264828, COSV61848713, COSV61853400; called by muse, mutect2, varscan2
- ZNF613 | c.1575A>G p.S525= (on ENST00000293471 / NM_001031721.4; = p.S489= on NM_024840.4) | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs759066031, COSV53271582; called by muse, mutect2, varscan2
- GLRXP3 | n.316C>A | RNA (SNP) | VAF 16/215 reads (7%) | catalogued as rs774706719; called by muse, mutect2
- RPS26P15 | n.129C>G | RNA (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
